Gene-level copy-number profile of tumor specimen TCGA-CV-7424-01A from TCGA case TCGA-CV-7424, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.8 years (24,775 days).
Specimen TCGA-CV-7424-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4fc7dc02-d2f4-45d9-bc4b-22aa247e3033.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7424-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c7d1c27c-b665-41be-9b08-d16985b89a52

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 406; copy number 2: 16,761; copy number 3: 21,845; copy number 4: 13,711; copy number 5: 3,969; copy number 6: 921; copy number 7: 77; copy number 8: 1,587; copy number 9: 268; copy number 10: 120; copy number 11: 6; copy number 12: 12; copy number 13: 60; copy number 14: 15; copy number 18: 28; copy number 26: 2; copy number 29: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7424-01A-11D-2077-01): tumor purity 0.48, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,208,082–141,208,376, 1 gene: RPS16P3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,198 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:58,275,532–64,088,246, 104 genes, copy number 9–29 (broad region; genes not listed).
- chr2:173,431,349–174,043,880, 12 genes, copy number 9: JPT1P1, CBY1P1, PPIAP66, AC013410.1, AC013410.2, AC106900.1, RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24.
- chr2:174,264,878–174,787,935, 18 genes, copy number 10: Y_RNA, LRRC2P1, HNRNPA1P39, LINC01305, AC018470.1, SP9, CIR1, SCRN3, GPR155, AC010894.1, RPA3P1, AC010894.4, AC010894.2, RNU6-5P, WIPF1, AC010894.3, H3P6, CHRNA1.
- chr2:177,227,595–177,392,697, 1 gene, copy number 9 (within-gene range 5–9): NFE2L2.
- chr2:177,283,508–178,108,339, 14 genes, copy number 9 (within-gene range 5–9): AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS, TTC30B, AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1.
- chr2:179,441,982–181,409,321, 17 genes, copy number 8–11 (within-gene range 5–11): ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22, AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437.
- chr2:199,269,500–199,471,266, 1 gene, copy number 9 (within-gene range 3–9): SATB2.
- chr2:199,457,700–200,830,116, 25 genes, copy number 9: SATB2-AS1, LINC01877, SEPHS1P6, FTCDNL1, AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1, AC004464.1, SPATS2L, RNY4P34, AC012459.1, KCTD18, SGO2, AOX1, AOX3P, AOX3P-AOX2P, LINC01792, AOX2P, RNU1-133P, BZW1-AS1, BZW1, RNU6-31P.
- chr2:201,620,184–201,643,570, 1 gene, copy number 9 (within-gene range 6–9): TMEM237.
- chr2:201,643,398–203,636,016, 62 genes, copy number 9 (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 8–18 (broad region; genes not listed).
- chr4:52,590,960–60,038,586, 131 genes, copy number 7–12 (broad region; genes not listed).
- chr4:61,906,313–63,351,472, 12 genes, copy number 8: Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11, EXOC5P1, AC097491.1, LARP1BP1.

Autosomal genes at a single copy (total copy number 1): 343. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
